Gene-level copy-number profile of specimen HCM-CSHL-0189-C25-85A from HCMI case HCM-CSHL-0189-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.9 years (23,328 days).
Specimen HCM-CSHL-0189-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e3941f37-6273-4cb3-bc4d-709c32ebcb2d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0189-C25-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/11806797-0537-44a6-8e60-78706c87d3a1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 2; copy number 2: 8,278; copy number 3: 2; copy number 4: 45,229; copy number 5: 1,812; copy number 6: 2,436; copy number 7: 57; copy number 8: 932; copy number 9: 92; copy number 10: 15; copy number 11: 8; copy number 12: 18; copy number 13: 3.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,446,824–25,089,151, 17 genes: DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 136 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,760,669, 9 genes, copy number 9: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1.
- chr1:146,064,711–146,237,807, 3 genes, copy number 12 (within-gene range 6–12): NBPF10, NOTCH2NLA, AC239799.1.
- chr1:147,840,962–147,842,359, 1 gene, copy number 9: AC239801.1.
- chr1:148,772,640–148,796,325, 2 genes, copy number 9: SEC22B3P, AC245389.1.
- chr1:158,560,606–158,579,899, 2 genes, copy number 9: OR6P1, OR10X1.
- chr1:191,858,707–191,890,229, 1 gene, copy number 10 (within-gene range 4–10): AL359081.1.
- chr5:18,547,312–19,234,487, 10 genes, copy number 10: RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr9:25,676,389–27,944,497, 30 genes, copy number 10–13: TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:32,455,302–32,980,403, 17 genes, copy number 9: DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, BOLA3P4, ASS1P12, TCEA1P4.
- chr9:33,218,365–33,282,070, 3 genes, copy number 9: SPINK4, BAG1, CHMP5.
- chr9:33,441,156–33,449,941, 2 genes, copy number 9: AQP3, AL356218.1.
- chr9:33,524,394–33,573,009, 1 gene, copy number 9: ANKRD18B.
- chr9:34,634,722–34,774,466, 12 genes, copy number 9: SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2, CCL19, AL162231.5, CCL21, FAM205A.
- chr9:34,957,608–35,011,285, 6 genes, copy number 9: PHF24, DNAJB5-DT, DNAJB5, AL355377.1, AL355377.2, SYF2P2.
- chr9:35,161,992–35,483,035, 4 genes, copy number 9: UNC13B, AL160274.1, ATP8B5P, ZFAND6P1.
- chr9:35,657,751–35,907,136, 26 genes, copy number 9: RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1.
- chr9:35,957,108–36,124,455, 7 genes, copy number 9 (within-gene range 8–9): OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
